Surgical pathology report (de-identified scan), TCGA case TCGA-QH-A65S, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Fondazione-Besta, specimen TCGA-QH-A65S-01A (Primary Tumor).

OBJECT: PATHOLOGIST REPORT

Code:

Gender: F

Age:

Date of surgery:

Localisation: temporal lobe

Diagnosis: oligoastrocytoma (grade 2 WHO)

Name of Pathologist:

ICD-O-3
Oligoastrocytoma 9382/3
Site ^{path} Brain, temporal lobe
CCF Brain, NOS
C71.2
C71.9
JA 4/19/13

3/29/13

Source: NCI Genomic Data Commons file bf2642ce-7496-46a7-9be8-46105d9bf87d (TCGA-QH-A65S.D970F3D5-D401-4BC0-A2FF-DBF7D0EDBA81.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).